FM case AD17297 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms.
https://portal.gdc.cancer.gov/cases/c6bf6ddd-e526-4ee3-96da-d01b16ed4438

Male, 72.1 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3); specimen biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Tumor.
